Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A3LQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A3LQ-01A (Primary Tumor).

[page 1 of 3]
Pathologist:
Assistant:
Date of Procedure:
Date Received:

Ordering M.D.:

Copies To:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. RIGHT PELVIC LYMPH NODE FROZEN SECTION:

- Metastatic poorly differentiated squamous cell carcinoma, the size of the metastasis is 2.5 cm, focally involving perinodal connective tissue

B. RIGHT PELVIC LYMPH NODE:

- Two lymph nodes, no tissue present

C. LEFT PELVIC LYMPH NODES:

- Three lymph nodes, no tissue present

D. UTERUS, CERVIX:

- Poorly differentiated squamous cell carcinoma cervix infiltrating to a depth of 14.0 mm with extensive lymphatic invasion
- The anterior-posterior size of the tumor is 6.8 cm
- The carcinoma extends to the posterior serosal surface and focally to parametrium
- The closest parametrial margin is at 3.0 mm from the carcinoma (right side)
- All margins of excision are negative for tumor
- Leiomyomas
- Localized adenomyosis

E. RIGHT COMMON ILIAC:

- Two lymph nodes, no tissue present

F. RIGHT TUBE AND OVARY:

- Ovary: inclusion cyst in the cortex
- Fallopian tube: no pathologic diagnosis

1CB-0-3

carcinoma, squamous cell 8090/3
Site: Cervix, NOS C53.9

12/20/11

HISTORY:

Per 1 Biopsy-proven invasive squamous cell carcinoma, also fibroids

MICROSCOPIC FINDINGS:

See diagnosis.

GROSS:

A. RIGHT PELVIC LYMPH NODE FS

Labeled with the patient's name designated "right pelvic lymph node", and received in formalin is a 5.2 x 0.8 x 0.6 cm lymph node. A section of the specimen has been submitted for frozen section analysis. Representative sections are submitted.

Slide key:

[page 2 of 3]
- A1. FSA1 remnant – 1
A2. Representative sections – 2

B. RIGHT PELVIC LYMPH NODE

Labeled with the patient's name _____, designated "right pelvic lymph node", and received in formalin are three lymph node candidates ranging in size from 2.0 to 2.4 cm in greatest dimension and aggregating to 2.9 x 2.4 x 0.7 cm. Entirely submitted.

Slide key:

- B1. Lymph nodes – 2
B2. Lymph node, bisected – 2

C. LEFT PELVIC LYMPH NODE

Labeled with the patient's name _____, designated "left pelvic lymph node", and received in formalin are two tan-brown lymph node candidates measuring 1.4 x 0.8 x 0.3 cm and 1.9 x 1.7 x 0.9 cm. Entirely submitted.

Slide key:

- C1. Lymph node – 1
C2. Lymph node, bisected – 2

D. UTERUS, CERVIX FOR RESEARCH

Labeled with the patient's name _____, designated "uterus, cervix", and received in formalin is a 529.5 gram hysterectomy specimen. No attached adnexal structures are present. The uterus is approximately 14.0 x 9.5 x 7.5 cm. The cervical portion of the uterus is approximately 4.6 cm in diameter, 3.5 cm in length between the two of them. The cervical os measures 1.5 cm in diameter. The posterior vaginal cuff measures 4.5 cm x 1.1 x 0.2 cm. The endometrium is 5.0 cm long and 1.0 cm in width and less than 0.1 cm throughout in thickness. The myometrial wall ranges in size from 1.5 to 3.0 cm in thickness.

The uterus is markedly distorted in shape due to the presence of a mass in the cervix and a large anterior leiomyoma. The cervical mass is 6.8 x 5.5 x 4.5 cm in greatest dimension and is friable, diffusely necrotic with areas of hemorrhage and with a well-circumscribed but infiltrative border. The cervical mass comes within 0.3 cm of the anterior inked surface and less than 0.1 cm of the posterior inked surface. Superiorly the cervical mass does not appear to be grossly invasive or extend beyond the lower uterine segment.

The anterior leiomyoma measures 8.5 x 7.5 x 7.5 cm and is composed of solid white-tan tissue with a whorled appearance. Additionally there are multiple (about ten) intramural leiomyomas ranging in size from 0.4 to 8.0 cm, one of which is subserosal. The myometrium is also suspicious for adenomyosis. No other endometrial lesions are identified.

Representative sections are submitted.

Gross photographs are taken.

Ink key:

Anterior resection margin – Blue.
Posterior resection margin – Black.

Slide key:

- D1. Closest posterior resection margin – 1
D2. Closest anterior resection margin – 1
D3. Tumor in relation to posterior vaginal cuff and transition zone – 1
D4. Tumor to serosa and tumor to serosa and normal appearing myometrium – 2
D5. Tumor to posterior resection margin – 1

[page 3 of 3]
- D6. Tumor to posterior resection margin – 1
D7, D8. Largest fibroid – 4 each
D9. Intramural fibroid and subserosal fibroid – 2
D10. Posterior endometrium through serosal surface and anterior endometrium (above largest fibroid) – 2
D11. Posterior lower uterine segment and myometrium suspicious for adenomyosis – 2
D12. Uninvolved cervix - 1

E. RIGHT COMMON ILIAC

Labeled with the patient's name designated "right common iliac", and received in formalin are two tan-brown lymph node candidates measuring 1.3 x 0.9 x 0.7 cm and 1.6 x 1.1 x 0.4 cm. Entirely submitted.

Slide key:

- E1. Two lymph node candidates – 2

F. RIGHT TUBE AND OVARY

Labeled with the patient's name designated "right tube and ovary", and received in formalin is a 12.12 gram salpingo-oophorectomy specimen. The ovary measures 3.1 x 1.5 x 1.4 cm. The fallopian tube measures 4.8 cm in length and ranges in diameter from 0.4 to 0.6 cm in greatest dimension. Cut surfaces show a hemorrhagic area within the ovary and a mucosa-filled fallopian tube lumen. Representative sections are submitted.

Slide key:

- F1. Ovary – 2
F2. Proximal mid and distal fallopian tube – 3

Gross dictated by

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

A. RIGHT PELVIC LYMPH NODE (FSA):

squamous cell carcinoma

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by Those
immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 09541fde-1679-41c5-8693-3381c6c21a96 (TCGA-DS-A3LQ.179CB483-18CC-4770-9C5E-22B5CC1E80C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).